MMRF case MMRF_1024 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/07d7c87a-409f-437d-bef8-36511773d540

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.0 years (29,222 days); ISS stage: II; Days to last known disease status: 1,927 days (5.3 years); Days to last follow up: 1,927 days (5.3 years).
   Treatment given: Therapeutic agents: Melphalan + Prednisone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 240 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 582 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 659 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 1): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 8.7 g/dL; Glucose 4.79 mmol/L.
- Day 106 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 25.9 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 5.02 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 5.61 mmol/L.
- Day 185 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.325 mg/dL; Immunoglobulin G 26.3 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 7.7 g/dL; Glucose 6.11 mmol/L.
- Day 240 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.967 mg/dL; Immunoglobulin G 23.7 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 1.4 ×10⁹/L; Absolute Neutrophil 0.3 ×10⁹/L; Platelets 36 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.83 mmol/L.
- Day 353 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 22.2 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.01 mmol/L.
- Day 439: M Protein 1.7 g/dL; Immunoglobulin G 19.5 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.28 mmol/L.
- Day 522 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.42 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.48 mmol/L.
- Day 624 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.678 mg/dL; Immunoglobulin G 23.5 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.97 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.39 mmol/L.
- Day 683 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.923 mg/dL; Immunoglobulin G 21.8 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.06 mmol/L.
- Day 779 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 25.3 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.
- Day 877 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.892 mg/dL; Immunoglobulin G 25.4 g/L; Beta 2 Microglobulin 3.25 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 35.3 g/L; Total Protein 7.7 g/dL; Glucose 4.95 mmol/L.
- Day 996 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 26.8 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 5.23 mmol/L.
- Day 1,052 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 26 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 5.39 mmol/L.
- Day 1,129 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 26.1 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.5 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 6 mmol/L.
- Day 1,234 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 24.7 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.56 mmol/L.
- Day 1,293 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 22.2 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 6.99 mmol/L.
- Day 1,412 (ECOG 2): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 26.5 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 5.12 mmol/L.
- Day 1,538 (ECOG 3): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 23.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 4.9 mmol/L.
- Day 1,606 (ECOG 2): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Immunoglobulin G 21 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 4.84 mmol/L.
- Day 1,681 (ECOG 2): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 19.6 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 1,741 (ECOG 3): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.
- Day 1,927 (ECOG 2): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -27: Weight: 52 kg; Height: 157 cm.

Biospecimens (4 samples)
- Sample MMRF_1024_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1024_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 240 days.
- Sample MMRF_1024_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 240 days.
- Sample MMRF_1024_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 439 days (1.2 years).
